Somatic mutation profile of tumor specimen C3N-04097-01 (aliquot CPT0285500006) from CPTAC case C3N-04097, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 71.3 years (26,058 days).
Specimen C3N-04097-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83f31cab-2b10-41b5-9df9-518ac42fe7b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04097-31 (Blood Derived Normal), aliquot CPT0285530002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7dbad69c-503a-4d3b-8bc8-3b3facca4dc3

The open-access MAF lists 93 somatic variants for this specimen: 64 protein-altering or splice-affecting, 19 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 19, Nonsense Mutation 5, RNA 4, Intron 3, Splice Region 2, 5'Flank 2, Frame Shift Ins 2, Splice Site 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2155G>A p.G719S | Missense Mutation (SNP) | VAF 5595/5929 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28929495, COSV51766606, COSV51767289; ClinVar: pathogenic / not provided / drug response; called by muse, mutect2, varscan2
- PIK3CA | c.1638G>T p.Q546H | Missense Mutation (SNP) | VAF 42/92 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1057519940, COSV55883555, COSV55928679, COSV55957396; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.451C>G p.P151A | Missense Mutation (SNP) | VAF 70/170 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537024957; called by muse, mutect2, varscan2
- ANK1 | c.2804G>A p.R935Q | Missense Mutation (SNP) | VAF 177/466 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780859723; called by muse, mutect2, varscan2
- ANKRD30B | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs754739467, COSV57704799; called by muse, mutect2, varscan2
- ATG9B | c.2755C>T p.R919W | Missense Mutation (SNP) | VAF 72/299 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as rs1312209539, COSV99871688; called by muse, mutect2, varscan2
- BCOR | c.4123C>T p.R1375W (on ENST00000378444 / NM_001123385.2; = p.R1341W on NM_017745.6) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV60700149; called by muse, mutect2, varscan2
- C12orf66 | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.071); catalogued as rs776484826; called by muse, mutect2, varscan2
- C2orf88 | c.11T>C p.M4T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs1457197042; called by muse, mutect2, varscan2
- CADPS | c.3475G>T p.E1159* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV99339173; called by mutect2, varscan2
- CXADR | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs749210959, COSV53028889; called by muse, mutect2, varscan2
- DCST2 | c.805+1G>A p.X269_splice | Splice Site (SNP) | VAF 8/17 reads (47%) | catalogued as rs374439255; called by muse, mutect2, varscan2
- DMD | c.7075C>A p.Q2359K | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT tolerated (0.87); PolyPhen benign (0.138); catalogued as CM098441, COSV58916236; called by muse, mutect2, varscan2
- FLI1 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs375383556; called by mutect2, varscan2
- FLT4 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057518359, COSV56100800, COSV56102768; ClinVar: uncertain significance; called by muse, mutect2
- FSD1 | c.801G>A p.A267= | Splice Region (SNP) | VAF 88/284 reads (31%) | catalogued as rs144315014; called by muse, mutect2
- HEPACAM2 | c.130G>A p.V44I (on ENST00000394468 / NM_001039372.4; = p.V32I on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/415 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769243743, COSV99052617; called by muse, mutect2, varscan2
- KRT12 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 104/252 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770184655, COSV52429589; called by muse, mutect2, varscan2
- MUC5AC | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 90/247 reads (36%) | SIFT deleterious (0); catalogued as COSV100650514; called by muse, mutect2, varscan2
- NEB | c.11015C>T p.T3672I | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1219709277; called by muse, mutect2, varscan2
- NMBR | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.417); catalogued as rs570950524, COSV57800824; called by muse, mutect2, varscan2
- NMUR2 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 91/190 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.957); catalogued as rs756384094, COSV54918385; called by muse, mutect2, varscan2
- NT5M | c.124A>G p.M42V | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs772697554; called by muse, mutect2, varscan2
- NUDT14 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 189/482 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs748155368; called by muse, mutect2, varscan2
- OR7G3 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV100555589; called by muse, mutect2, varscan2
- PAK5 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 108/238 reads (45%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs745765163, COSV100781002, COSV62027225; called by muse, mutect2, varscan2
- RGPD4 | c.2339C>T p.T780I | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1362543502; called by muse, mutect2, varscan2
- TAF1L | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs962298164; called by muse, mutect2, varscan2
- TMIGD3 | c.729G>A p.R243= (on ENST00000369717 / NM_001081976.2; = p.R324= on NM_020683.7) | Splice Region (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100778438; called by muse, mutect2, varscan2
- TRIM51 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs755032979, COSV55267715; called by muse, mutect2, varscan2
- TRPV6 | c.2047C>T p.R683W | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs775632242, COSV63890810; called by muse, mutect2
- XDH | c.3233C>T p.T1078M | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748919252, COSV65146943; called by muse, mutect2, varscan2
- ZNF438 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 70/95 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs751881615, COSV59198808; called by muse, mutect2, varscan2
- AGR2 | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 51/284 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- C9orf16 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNA1F | c.56G>C p.G19A | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.108); called by muse, varscan2
- CDH2 | c.1702A>C p.N568H | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- CEP41 | c.55C>G p.Q19E | Missense Mutation (SNP) | VAF 73/379 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CFAP20DC | c.1319C>T p.S440F (on ENST00000482387 / NM_001351530.2; = p.S315F on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHD2 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DGKZ | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 90/211 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DGKZ | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.027); called by muse, mutect2
- DSP | c.7304dup p.D2436Gfs*2 | Frame Shift Ins (INS) | VAF 70/217 reads (32%) | called by mutect2, pindel, varscan2
- FBN2 | c.4229A>G p.D1410G | Missense Mutation (SNP) | VAF 100/265 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRM3 | c.2363T>C p.I788T | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- HELT | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 110/280 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- IQGAP3 | c.3188_3195dup p.D1066Cfs*2 | Nonsense Mutation (INS) | VAF 79/289 reads (27%) | called by mutect2, varscan2
- KMT2E | c.554C>A p.S185* | Nonsense Mutation (SNP) | VAF 25/186 reads (13%) | called by muse, mutect2, varscan2
- OR5B21 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDCD6IP | c.645A>T p.K215N | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDCL | c.725dup p.E243* | Frame Shift Ins (INS) | VAF 56/143 reads (39%) | called by mutect2, pindel, varscan2
- PI4KB | c.304G>A p.D102N (on ENST00000368873 / NM_001369623.1; = p.D114N on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SCN7A | c.2609G>A p.S870N | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SLC1A6 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 109/231 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- SPICE1 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TMOD4 | c.287C>A p.P96H | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- TRIM62 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 60/143 reads (42%) | called by muse, mutect2, varscan2
- TRIM67 | c.484T>G p.C162G | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UGT2B15 | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- VPS13D | c.2246G>A p.R749K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- YTHDF3 | c.1032G>T p.Q344H | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF107 | c.1635_1638del p.H546Lfs*26 | Frame Shift Del (DEL) | VAF 24/141 reads (17%) | called by mutect2, pindel, varscan2
- ZNF112 | c.2572G>T p.E858* (on ENST00000337401 / NM_001083335.2; = p.E852* on NM_013380.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 60/121 reads (50%) | called by muse, mutect2, varscan2
- ABCA6 | c.4656C>T p.D1552= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs769359582, COSV52637693; called by muse, mutect2, varscan2
- AC011455.2 | c.678G>A p.E226= | Silent (SNP) | VAF 18/343 reads (5%) | called by muse, mutect2
- ADAMTS12 | c.3687C>T p.S1229= | Silent (SNP) | VAF 72/177 reads (41%) | catalogued as rs555561274, COSV61266250; called by muse, mutect2, varscan2
- ADAMTS20 | c.3609C>T p.D1203= | Silent (SNP) | VAF 42/126 reads (33%) | catalogued as rs760807153; called by muse, mutect2, varscan2
- CCDC149 | c.475C>A p.R159= | Silent (SNP) | VAF 89/205 reads (43%) | catalogued as COSV60879603; called by muse, mutect2, varscan2
- CCNH | c.519C>T p.D173= | Silent (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2
- FAM162B | c.300C>T p.T100= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs763643940, COSV63920182; called by muse, mutect2, varscan2
- LILRB1 | c.1131C>T p.N377= (on ENST00000427581; = p.N341= on NM_006669.6) | Silent (SNP) | VAF 49/142 reads (35%) | catalogued as rs201120319; called by muse, mutect2, varscan2
- MAVS | c.702C>T p.T234= | Silent (SNP) | VAF 71/162 reads (44%) | catalogued as rs1321803146; called by muse, mutect2, varscan2
- MGAM2 | c.141C>T p.P47= | Silent (SNP) | VAF 34/244 reads (14%) | catalogued as COSV72176162; called by muse, mutect2, varscan2
- RFPL4A | c.468C>T p.D156= | Silent (SNP) | VAF 40/412 reads (10%) | catalogued as rs1307623235; called by mutect2, varscan2
- RFPL4AL1 | c.468C>T p.D156= | Silent (SNP) | VAF 110/648 reads (17%) | catalogued as rs1227823061; called by muse, varscan2
- SERPINA1 | c.1095C>T p.D365= | Silent (SNP) | VAF 105/274 reads (38%) | catalogued as rs201774333; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TTC34 | c.1992C>T p.G664= | Silent (SNP) | VAF 69/167 reads (41%) | catalogued as rs897478379; called by muse, mutect2, varscan2
- TTN | c.25578G>A p.T8526= (on ENST00000591111; = p.T7599= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as rs747558822, COSV60019924, COSV60069038; called by muse, mutect2
- TTN | c.2685C>T p.G895= (on ENST00000591111; = p.G849= on NM_003319.4) | Silent (SNP) | VAF 97/256 reads (38%) | catalogued as rs139501351; called by muse, mutect2, varscan2
- ZNF280A | c.147C>T p.V49= | Silent (SNP) | VAF 48/138 reads (35%) | catalogued as rs762725294; called by muse, mutect2, varscan2
- ZNF407 | c.5367G>A p.R1789= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as rs777189322; called by muse, mutect2, varscan2
- ZNF781 | c.567C>G p.L189= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as rs1310048169, COSV62203061; called by muse, mutect2, varscan2
- AGAP12P | n.1718_1720del | RNA (DEL) | VAF 133/225 reads (59%) | called by pindel, varscan2
- AGAP3 | c.224-1446C>T | Intron (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- ATM | c.*7G>A | 3'UTR (SNP) | VAF 47/115 reads (41%) | called by muse, mutect2, varscan2
- CEP170P1 | n.4279G>A | RNA (SNP) | VAF 24/72 reads (33%) | catalogued as rs1309903020; called by muse, mutect2, varscan2
- DAP3 | c.994-14T>G | Intron (SNP) | VAF 71/184 reads (39%) | catalogued as rs1285232177; called by muse, mutect2, varscan2
- DCHS2 | n.5004G>T | RNA (SNP) | VAF 53/123 reads (43%) | catalogued as COSV61772506; called by muse, mutect2, varscan2
- ELOBP3 | chr2:48776288 T>C | 5'Flank (SNP) | VAF 48/125 reads (38%) | called by muse, mutect2, varscan2
- FOXP2 | chr7:114086473 C>T | 5'Flank (SNP) | VAF 44/152 reads (29%) | catalogued as rs1448113557; called by mutect2, varscan2
- RIMS2 | c.2084-945C>T | Intron (SNP) | VAF 60/122 reads (49%) | catalogued as rs760633704, COSV51655828; called by muse, mutect2, varscan2
- SPATA31C1 | n.1021C>T | RNA (SNP) | VAF 142/350 reads (41%) | catalogued as rs560034208; called by muse, mutect2, varscan2
